Somatic mutation profile of tumor specimen 0DTUIU from CCDI case PBCKHM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 2.8 years (1,020 days).
Specimen 0DTUIU: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f5e72d6-2e47-4ef9-811d-5863aa345d60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTUI5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e44f0eca-8cd9-4612-b880-f0fe7f542231

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Intron 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNRNPH1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 142/561 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100270589, COSV61487590, COSV61487822; called by muse, varscan2
- OPRK1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 148/374 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55573223; called by muse, mutect2, varscan2
- SIVA1 | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 108/256 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317966339; called by muse, varscan2
- AMOT | c.568del p.A190Pfs*41 | Frame Shift Del (DEL) | VAF 184/544 reads (34%) | called by mutect2, pindel, varscan2
- COL7A1 | c.8408C>A p.A2803D | Missense Mutation (SNP) | VAF 195/510 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LILRA5 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 143/403 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- DUSP4 | c.1062C>A p.G354= | Silent (SNP) | VAF 205/474 reads (43%) | called by muse, mutect2, varscan2
- MIA3 | c.2517A>C p.P839= | Silent (SNP) | VAF 193/464 reads (42%) | called by muse, mutect2, varscan2
- SERINC5 | c.138C>T p.V46= | Silent (SNP) | VAF 203/656 reads (31%) | catalogued as COSV72596307; called by muse, varscan2
- C8B | c.1621+21A>G | Intron (SNP) | VAF 15/270 reads (6%) | called by muse, mutect2
- FCGR1A | c.*20C>T | 3'UTR (SNP) | VAF 143/334 reads (43%) | catalogued as rs1269072816, COSV100977260; called by muse, mutect2, varscan2
- GAS6 | c.344-94A>T | Intron (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2
